Gene-level copy-number profile of tumor specimen TCGA-CV-7254-01A from TCGA case TCGA-CV-7254, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 55.6 years (20,306 days).
Specimen TCGA-CV-7254-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.37955223-cc46-407b-8c47-a8af7401e984.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7254-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/79c09fc1-ac1f-4fc0-91b3-2850f4dd8ead

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 4,524; copy number 2: 23,876; copy number 3: 10,807; copy number 4: 11,496; copy number 5: 4,344; copy number 6: 2,089; copy number 7: 1,814; copy number 8: 2; copy number 9: 401; copy number 11: 443; copy number 17: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7254-01A-11D-2010-01): tumor purity 0.37, ploidy 2.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–409,417, 7 genes (within-gene range 0–1): LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,884 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–2,840,512, 45 genes, copy number 5: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1, MYT1L-AS1, AC018685.2, AC018685.3, AC011995.2, AC018685.1.
- chr2:198,299,276–199,476,935, 8 genes, copy number 8–17: LINC01923, AC019330.1, AC020718.1, AC018717.1, RNU7-147P, SATB2, AC016746.1, SATB2-AS1.
- chr2:199,760,544–200,482,264, 11 genes, copy number 5 (within-gene range 2–5): FTCDNL1, AC097717.1, AC108032.1, RN7SL717P, C2orf69, TYW5, MAIP1, AC004464.1, SPATS2L, RNY4P34, AC012459.1.
- chr2:209,178,804–210,022,260, 8 genes, copy number 5 (within-gene range 2–5): MEAF6P1, PKP4P1, AC016743.1, MAP2, RNA5SP118, UNC80, SNAI1P1, RPE.
- chr3:153,881,526–198,222,513, 784 genes, copy number 7–11 (within-gene range 4–11) (broad region; genes not listed).
- chr5:17,065,598–20,575,873, 62 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr5:30,365,405–30,365,684, 1 gene, copy number 5: AC114300.1.
- chr5:33,888,056–35,230,487, 28 genes, copy number 6 (within-gene range 3–6): RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1, AC138409.3, AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1.
- chr5:35,852,695–38,608,354, 56 genes, copy number 6 (within-gene range 3–6): IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR.
- chr5:38,557,502–38,557,561, 1 gene, copy number 6: MIR3650.
- chr5:75,320,155–79,534,954, 86 genes, copy number 5 (broad region; genes not listed).
- chr7:67,627,831–68,319,676, 10 genes, copy number 6: MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3.
- chr7:71,132,144–85,636,344, 251 genes, copy number 5–6 (broad region; genes not listed).
- chr7:86,643,914–109,764,357, 493 genes, copy number 7–9 (broad region; genes not listed).
- chr7:118,880,103–124,489,572, 63 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:136,685,559–150,861,504, 405 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:47,592,147–145,066,685, 1,500 genes, copy number 5 (broad region; genes not listed).
- chr9:14,475–67,920,552, 939 genes, copy number 5–7 (broad region; genes not listed).
- chr9:78,741,720–83,069,143, 45 genes, copy number 7: MTND2P8, KRT18P24, AL512634.1, CHCHD2P9, LNCARSR, TLE4, AL161912.3, NPAP1P6, AL161912.1, AL161912.2, AL161912.4, AL161782.1, LINC01507, NPAP1P4, MTCO1P51, MTND2P9, RPS19P6, AL138749.1, RPS20P25, AL161727.1, TLE1, AL591368.1, RNU6-1035P, RNA5SP287, AL158154.1, SPATA31D5P, AL158154.2, SPATA31D4, AL158154.3, SPATA31D3, SPATA31D2P, AL162726.3, SPATA31D1, SPATA31B1P, DDX10P2, AL158047.1, AL162726.1, MTCO3P40, AL162726.2, AL162726.4, AL356490.1, AL353774.1, RPS6P12, RASEF, AL499602.1.
- chr10:44,712–42,475,349, 683 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:58,579,063–59,214,699, 26 genes, copy number 9: ZFP91, ZFP91-CNTF, AP001350.1, CNTF, AP001350.2, GLYAT, AP000445.1, AP000445.2, TMA16P1, GLYATL2, GLYATL1P2, GLYATL1, AP001652.1, AP001636.3, AP001636.2, GLYATL1P1, AP001636.1, GLYATL1P4, GLYATL1B, FAM111B, FAM111A-DT, AP001258.1, FAM111A, DTX4, MPEG1, RN7SL42P.
- chr12:66,767–34,249,958, 850 genes, copy number 5–9 (broad region; genes not listed).
- chr12:78,052,181–80,680,273, 29 genes, copy number 5 (within-gene range 2–5): AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2, SYT1, AC090709.1, AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1, RN7SKP261, PTPRQ.
- chr14:55,559,072–56,117,990, 7 genes, copy number 6: KTN1, Y_RNA, AL355773.1, RPL13AP3, LINC00520, AL163952.1, AL138995.1.
- chr14:83,986,776–88,555,007, 42 genes, copy number 11 (within-gene range 3–11): AL356807.1, MTND4P33, MTND5P35, MTCYBP27, RNU6-976P, AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2, LINC02328, LINC02316, AL161753.1, LINC02309, LINC01148, AL358292.1, AL352955.1, AL157688.1, LINC02296, AL135746.1, LINC02330, AL359237.1, AL136501.1, GALC, SHLD2P2, RNU6-835P, GPR65, AL157955.1, LINC01147, LINC01146, AL133279.2, AL133279.3, AL133279.1, KCNK10, SPATA7, PTPN21, AL162171.2, RNU4-22P.
- chr15:62,304,658–101,933,350, 1,035 genes, copy number 6 (broad region; genes not listed).
- chr17:28,926,275–37,884,743, 363 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:26,167,817–37,445,534, 261 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr22:15,290,718–27,920,134, 646 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr22:45,284,949–47,175,699, 43 genes, copy number 6 (within-gene range 2–6): UPK3A, FAM118A, SMC1B, RIBC2, AL021391.1, FBLN1, LINC01589, RNU6-1161P, Z95331.1, ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1, WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B, PPARA, FP325332.1, CDPF1, PKDREJ, TTC38, GTSE1-DT, GTSE1, TRMU, CELSR1, AL031597.1, AL021392.1, GRAMD4, CERK, AL118516.1, TBC1D22A.
- chr22:47,115,838–50,801,309, 103 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,894. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
